Somatic mutation profile of tumor specimen TCGA-JW-A5VK-01A (aliquot TCGA-JW-A5VK-01A-11D-A28B-09) from TCGA case TCGA-JW-A5VK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary squamous cell carcinoma; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 43.7 years (15,965 days).
Specimen TCGA-JW-A5VK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 443c49bc-2add-4191-bffe-fee5480c4fe1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JW-A5VK-10A (Blood Derived Normal), aliquot TCGA-JW-A5VK-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac4560e3-1db1-400b-ba2b-99d900ec28f8

The open-access MAF lists 49 somatic variants for this specimen: 35 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 13, Frame Shift Del 4, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM2A | c.580T>A p.F194I (on ENST00000219054; = p.F115I on NM_001308169.2) | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV54583422, COSV99525330; called by muse, mutect2, varscan2
- ADAR | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as rs1454970654, COSV52713412; called by muse, mutect2, varscan2
- AFF1 | c.2009A>G p.K670R | Missense Mutation (SNP) | VAF 50/54 reads (93%) | SIFT tolerated (0.34); PolyPhen benign (0.066); catalogued as COSV57118333; called by muse, mutect2, varscan2
- ARHGAP27 | c.1097C>A p.S366* (on ENST00000428638 / NM_001282290.1; = p.S25* on NM_199282.3) | Nonsense Mutation (SNP) | VAF 37/101 reads (37%) | catalogued as COSV100976439, COSV65357310; called by muse, mutect2, varscan2
- ATP8A2 | c.2923C>T p.L975F | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54938696, COSV54944361; called by muse, mutect2, varscan2
- CBLN4 | c.499C>T p.L167F | Missense Mutation (SNP) | VAF 63/108 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV50352413; called by muse, mutect2, varscan2
- COL5A1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as rs761079177, COSV65667285; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- DDX39A | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV54390871; called by muse, mutect2, varscan2
- DNAJC1 | c.1180G>C p.V394L | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV65409977; called by muse, mutect2, varscan2
- ENC1 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56629069; called by muse, mutect2, varscan2
- ERLEC1 | c.112A>C p.S38R | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV51751050; called by muse, mutect2, varscan2
- FLT3 | c.2144C>T p.T715I | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV54048617; called by muse, mutect2, varscan2
- GSTA5 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 99/192 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52861536, COSV52861780; called by muse, mutect2, varscan2
- INTS7 | c.1007G>A p.S336N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as rs1183847754, COSV65343978; called by muse, mutect2, varscan2
- KEAP1 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV50260660; called by muse, mutect2, varscan2
- MCF2L | c.911C>G p.A304G (on ENST00000375608; = p.A272G on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV65049661; called by muse, mutect2, varscan2
- MEGF9 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.322); catalogued as COSV64235014; called by muse, mutect2, varscan2
- OR8K3 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs766060464, COSV57130713, COSV57130774; called by muse, mutect2, varscan2
- PEAR1 | c.2902C>T p.R968W | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs528435112, COSV52772079; called by muse, mutect2, varscan2
- PER3 | c.3455del p.K1152Rfs*46 | Frame Shift Del (DEL) | VAF 35/89 reads (39%) | catalogued as rs773961726; called by mutect2, pindel, varscan2
- PLEC | c.8887G>A p.V2963M (on ENST00000322810 / NM_201380.4; = p.V2853M on NM_000445.5) | Missense Mutation (SNP) | VAF 81/176 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.688); catalogued as rs371422018; called by muse, mutect2, varscan2
- PTAFR | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 105/203 reads (52%) | catalogued as COSV59536388, COSV59538007; called by muse, mutect2, varscan2
- RALGAPA2 | c.515A>T p.E172V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV52492735; called by muse, mutect2, varscan2
- RIMS1 | c.3077C>A p.A1026E | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as COSV99325751; called by muse, mutect2, varscan2
- RPS6KA2 | c.2126C>T p.P709L | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.982); catalogued as rs555832127, COSV55818214; called by muse, mutect2, varscan2
- SHANK2 | c.2672C>T p.P891L | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1017806518, COSV53591299; called by muse, mutect2, varscan2
- SOGA3 | c.1987G>A p.V663M | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1006473658, COSV64105841; called by muse, mutect2, varscan2
- TKFC | c.937del p.S313Lfs*12 | Frame Shift Del (DEL) | VAF 61/170 reads (36%) | catalogued as COSV67523361; called by mutect2, pindel, varscan2
- TMEM74B | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201827576, COSV67892237; called by muse, mutect2, varscan2
- XKR4 | c.478C>G p.Q160E | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1261876893, COSV59306981; called by muse, mutect2, varscan2
- ZMIZ1 | c.2845G>A p.A949T | Missense Mutation (SNP) | VAF 60/65 reads (92%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.047); catalogued as rs753707755, COSV57892474; called by muse, mutect2, varscan2
- CUL3 | c.2176-2_2176-1insTG p.X726_splice | Splice Site (INS) | VAF 19/32 reads (59%) | called by mutect2, pindel*, varscan2
- KLF5 | c.282_288del p.Y95Hfs*9 | Frame Shift Del (DEL) | VAF 25/51 reads (49%) | called by mutect2, pindel, varscan2
- KMT2D | c.9109dup p.H3037Pfs*4 | Frame Shift Ins (INS) | VAF 19/47 reads (40%) | called by mutect2, pindel, varscan2
- KMT2D | c.6737_6758del p.K2246Ifs*11 | Frame Shift Del (DEL) | VAF 39/68 reads (57%) | called by mutect2, pindel, varscan2
- DSCAM | c.234C>T p.N78= | Silent (SNP) | VAF 35/74 reads (47%) | catalogued as rs770298655, COSV101258638, COSV68626120; called by muse, mutect2, varscan2
- ITGA4 | c.858T>A p.I286= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV51998937; called by muse, mutect2, varscan2
- LCOR | c.4473G>A p.L1491= | Silent (SNP) | VAF 10/10 reads (100%) | catalogued as COSV53715100; called by muse, mutect2, varscan2
- MAP3K11 | c.1125G>A p.Q375= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as rs1281775350, COSV58418909; called by muse, mutect2, varscan2
- OAZ2 | c.558C>T p.S186= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs201520056, COSV58106507; called by muse, mutect2, varscan2
- OR10G8 | c.837G>A p.T279= | Silent (SNP) | VAF 150/167 reads (90%) | catalogued as rs138666219; called by muse, mutect2, varscan2
- PCDHGA2 | c.1854G>A p.S618= | Silent (SNP) | VAF 130/267 reads (49%) | catalogued as COSV53919835; called by muse, mutect2, varscan2
- PLD1 | c.1419G>A p.S473= | Silent (SNP) | VAF 56/114 reads (49%) | catalogued as rs758110993, COSV60566472; called by muse, mutect2, varscan2
- SYT4 | c.582C>A p.I194= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as COSV54899255, COSV54902499; called by muse, mutect2, varscan2
- TENM2 | c.6402C>T p.V2134= (on ENST00000518659 / NM_001122679.2; = p.V1895= on NM_001080428.3) | Silent (SNP) | VAF 47/90 reads (52%) | catalogued as COSV69126692; called by muse, mutect2, varscan2
- TIMM21 | c.570C>T p.H190= | Silent (SNP) | VAF 56/130 reads (43%) | catalogued as COSV99400053; called by muse, mutect2, varscan2
- TMEM98 | c.657C>T p.F219= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV55582440; called by muse, mutect2, varscan2
- UBR4 | c.6561G>A p.P2187= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs373836724; called by muse, mutect2, varscan2
- SNORD115-32 | n.26G>T | RNA (SNP) | VAF 30/36 reads (83%) | catalogued as rs369979609; called by muse, mutect2, varscan2
